Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANM, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AANM-01A (Primary Tumor).

[page 1 of 2]
Ord #=

RESULTED

Collect D/T=

SURGICAL PATHOL

Modifiers:

(1 of 1)

Surgical Pathology Report

Specimen(s) Received

A: Right testical
B: Cord lipoma

Clinical History

None stated

Gross Description

Received in one formalin container labeled with patient's name and medical record number:

A. Right testicle: The specimen consists of a 55-gm testicle measuring 5.8 x 4.5 x 3.8 cm. There is a portion of spermatic cord attached that measures 7 cm in length and 1.5 cm in diameter. Its proximal most portion is inked in black. The testicle has been previously bisected and its cut surface consists of a well circumscribed soft, white tan, homogenous-appearing mass that measures 4.5 x 3.8 x 2.9 cm and stays within the testicle. Areas of yellow and red discoloration are present in a small area (<5% of mass). A small rim of normal-appearing testis measuring 1.5 x 1.5 x 0.5 cm is still present. A piece of mass tissue from was previously submitted for research. No other gross abnormalities are noted.

Representative sections are submitted as follows:

A1: Spermatic cord with margin

A2-5: Representative sections of tumor

B. Cord lipoma: The specimen consists of a piece of yellow, glistening adipose tissue that is soft and unoriented and measures 5.0 x 3.0 x 1.5 cm and is partially covered by a translucent, elastic, shiny tissue. The specimen is entirely inked in black. Sectioning reveals a soft, homogenous, yellow surface without hemorrhage, necrosis or areas of firmness. Representative sections are submitted in one cassette. B1

Date of dictation:

ICD.O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
JWS/3/1/14

[page 2 of 2]
(continued)

Acct#:

Gross Description By:

Microscopic Description
Performed.

Final Pathologic Diagnosis

A. Specimen Type: Orchiectomy

Laterality: Right Focality: Unifocal

Tumor Size: 4.3 cm

Histologic Type: Seminoma, pure

Intratubular germ cell neoplasia is not identified

Tumor is limited to the testis. Tumor does not involve rete testis, epididymis, perihilar fat, spermatic cord, tunica vaginalis or scrotal wall.

Lymphovascular Invasion: Not identified

Margin: Spermatic cord margin is negative for tumor

Pathologic Tumor Stage: pT1NXMX (Stage IS)

B. Cord lipoma: Lipoma

Attending Pathologist:

***Electronically Signed Out By

Patient Name:

Case #:

Med. Rec. #:

Location:

Date Collected:

Source: NCI Genomic Data Commons file 47d55e8a-ea51-4cab-b102-c7c16b40483d (TCGA-XE-AANM-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).